Somatic mutation profile of tumor specimen ALCH-B2P1-TTP1-A (aliquot ALCH-B2P1-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2P1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.2 years (23,809 days).
Specimen ALCH-B2P1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc7bf600-c5da-4b04-9999-86d48bf3495e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2P1-NB1-A (Blood Derived Normal), aliquot ALCH-B2P1-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab0471db-d977-47f1-9338-c05c12a72fb4

The open-access MAF lists 381 somatic variants for this specimen: 247 protein-altering or splice-affecting, 86 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 212, Silent 86, Intron 23, Nonsense Mutation 18, RNA 11, Frame Shift Del 7, 3'UTR 6, 5'UTR 5, Splice Site 4, Splice Region 4, 5'Flank 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.6914C>A p.P2305H | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100718132; called by muse, mutect2
- ANK1 | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 101/796 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs150655828; called by muse, mutect2, varscan2
- BRINP1 | c.1756C>A p.R586S | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs149339295, COSV56309045; called by muse, mutect2, varscan2
- CACNA1E | c.6341C>T p.P2114L (on ENST00000367573 / NM_001205293.3; = p.P2071L on NM_000721.4) | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs759886074; called by muse, mutect2
- CGNL1 | c.3478G>T p.D1160Y | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV55572630; called by muse, mutect2
- CLEC17A | c.1038C>A p.H346Q | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV60427180; called by muse, mutect2, varscan2
- COL11A1 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62181594; called by muse, mutect2
- CRACD | c.3430C>A p.L1144M | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV51729857; called by muse, mutect2, varscan2
- CRNKL1 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs141785689; called by muse, mutect2, varscan2
- CSMD3 | c.2278C>A p.H760N (on ENST00000297405 / NM_001363185.1; = p.H656N on NM_052900.3) | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99841629; called by muse, mutect2, varscan2
- CYBA | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99879827; called by muse, mutect2, varscan2
- CYP4F12 | c.1315-4G>T | Splice Region (SNP) | VAF 57/416 reads (14%) | catalogued as rs1350493718; called by muse, mutect2, varscan2
- DAB2 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1158215139, COSV57919008; called by muse, mutect2, varscan2
- DNAJC5B | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 58/675 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as rs748413301, COSV99396043; called by muse, mutect2
- DUSP26 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56362545; called by muse, mutect2, varscan2
- EDEM2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs974106680; called by muse, mutect2
- EDN3 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM101978, COSV61109096; called by muse, mutect2, varscan2
- EFL1 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 76/688 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs749280041; called by muse, mutect2, varscan2
- ERICH3 | c.2686G>T p.E896* | Nonsense Mutation (SNP) | VAF 31/323 reads (10%) | catalogued as COSV100444949; called by muse, mutect2
- EXOSC10 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58666673; called by muse, mutect2
- FAM135B | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs370285922; called by muse, mutect2, varscan2
- FBN1 | c.7743C>A p.C2581* | Nonsense Mutation (SNP) | VAF 40/531 reads (8%) | catalogued as CM022009; called by muse, mutect2
- FBXL7 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as COSV61652488; called by muse, mutect2
- GLB1L3 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs930341802; called by muse, mutect2, varscan2
- GOLM1 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99974237; called by muse, mutect2, varscan2
- IQCH | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 70/664 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60053162; called by muse, mutect2, varscan2
- JAKMIP2 | c.1298C>A p.P433Q | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99507685; called by muse, mutect2, varscan2
- KCND1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV54416397, COSV99501697; called by muse, mutect2, varscan2
- KCNK10 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 88/671 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56652447; called by muse, mutect2, varscan2
- KCNQ2 | c.1295G>C p.R432P | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV60546233; called by muse, mutect2, varscan2
- KDM5A | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1404815403; called by muse, mutect2, varscan2
- KEAP1 | c.911del p.I304Tfs*13 | Frame Shift Del (DEL) | VAF 31/198 reads (16%) | catalogued as COSV50279660; called by mutect2, pindel, varscan2
- KLK8 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs779313970; called by muse, mutect2, varscan2
- KRT25 | c.160T>A p.S54T | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56446742; called by muse, mutect2, varscan2
- LAG3 | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV52566923; called by muse, mutect2, varscan2
- LINGO1 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100796362; called by mutect2, varscan2
- LRRC55 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV73006863; called by muse, mutect2, varscan2
- MACC1 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1400250082; called by muse, mutect2, varscan2
- MAGEB2 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.577); catalogued as COSV66781438; called by muse, mutect2, varscan2
- MORC1 | c.297C>A p.Y99* | Nonsense Mutation (SNP) | VAF 26/454 reads (6%) | catalogued as COSV51718292; called by muse, mutect2
- MOSPD2 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.444); catalogued as rs769665676; called by muse, mutect2, varscan2
- MYH6 | c.5678C>A p.T1893N | Missense Mutation (SNP) | VAF 90/578 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100198249; called by muse, mutect2, varscan2
- NAV2 | c.1663A>T p.M555L (on ENST00000396087 / NM_001244963.2; = p.M532L on NM_145117.5) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs750615660; called by muse, mutect2
- NEUROD4 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54472942, COSV99670241; called by muse, mutect2
- NGEF | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs1162092635; called by muse, mutect2
- NISCH | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761859877; called by muse, mutect2, varscan2
- OR2T6 | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63217019; called by muse, mutect2, varscan2
- OR4C12 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.314); catalogued as rs1430272182, COSV100078426; called by muse, mutect2
- OR5I1 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs575836357, COSV56889081; called by muse, mutect2, varscan2
- OSR2 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV52557892, COSV52558339; called by muse, mutect2, varscan2
- PALLD | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as COSV99824847; called by muse, mutect2, varscan2
- PATZ1 | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.737); catalogued as rs939636305, COSV99315752; called by muse, mutect2, varscan2
- PCDHA4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); catalogued as rs781791401, COSV63538555; called by muse, mutect2
- PCDHB7 | c.1563C>G p.Y521* | Nonsense Mutation (SNP) | VAF 91/653 reads (14%) | catalogued as COSV50806337, COSV50823869; called by muse, varscan2
- PILRA | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 47/345 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV52199660; called by muse, mutect2, varscan2
- POTEF | c.3222C>A p.C1074* | Nonsense Mutation (SNP) | VAF 50/574 reads (9%) | catalogued as COSV62541506; called by muse, mutect2
- PREX2 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55794056; called by muse, mutect2, varscan2
- PREX2 | c.4492T>A p.C1498S | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.041); catalogued as COSV55791100; called by muse, mutect2, varscan2
- PTEN | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 65/485 reads (13%) | catalogued as rs1554825210, COSV64291584, COSV64299810; called by muse, mutect2, varscan2
- RGS18 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1024305282, COSV66510175; called by muse, mutect2
- RMC1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 20/459 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1416973722, COSV99339812; called by muse, mutect2
- SAMD11 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1288733664; called by muse, mutect2, varscan2
- SCML4 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64634780; called by muse, mutect2
- SEL1L2 | c.1961G>A p.W654* | Nonsense Mutation (SNP) | VAF 19/158 reads (12%) | catalogued as rs773390427; called by muse, mutect2, varscan2
- SERPINA7 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.198); catalogued as rs185176881, COSV59664805, COSV59665125; called by muse, mutect2, varscan2
- SLC45A1 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as COSV99238586; called by muse, mutect2, varscan2
- SPATA48 | c.1279C>G p.P427A | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs1438586044, COSV51674416; called by muse, mutect2, varscan2
- SSX1 | c.*4del | Splice Region (DEL) | VAF 28/131 reads (21%) | catalogued as COSV65354945; called by mutect2, pindel, varscan2
- TAAR6 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 56/358 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as rs770728288; called by muse, mutect2, varscan2
- TACR3 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1308179178; called by muse, mutect2, varscan2
- TAS1R2 | c.1287C>A p.F429L | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV64745147; called by muse, mutect2
- TMC4 | c.472G>T p.A158S (on ENST00000617472 / NM_001145303.3; = p.A152S on NM_144686.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as rs754668617; called by muse, mutect2
- TP53 | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 105/644 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as CM137622, COSV52705216, COSV52823842, COSV53165376, COSV53486085; called by muse, mutect2, varscan2
- YBX3 | c.223_225del p.T75del | In Frame Del (DEL) | VAF 9/110 reads (8%) | catalogued as rs776087407; called by mutect2, pindel
- ZEB2 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV57958275; called by muse, mutect2, varscan2
- ZFHX4 | c.6447C>G p.D2149E | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99269402; called by muse, mutect2
- A2ML1 | c.2324G>A p.G775D | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC132217.2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- AGO2 | c.1816G>T p.G606W | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- AKAP6 | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- AKAP9 | c.4146A>G p.P1382= | Splice Region (SNP) | VAF 53/512 reads (10%) | called by muse, mutect2, varscan2
- AKIRIN2 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ANGPT1 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 31/333 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.5370A>T p.R1790S | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ANK3 | c.12496A>G p.I4166V (on ENST00000280772 / NM_001320874.2; = p.I687V on NM_001149.3) | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ANK3 | c.7739C>G p.T2580S | Missense Mutation (SNP) | VAF 62/426 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARHGAP35 | c.3826G>A p.G1276R | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AWAT1 | c.72del p.I25Sfs*45 | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel, varscan2
- BTBD7 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); called by muse, mutect2
- BVES | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CASP12 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 57/585 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- CCDC138 | c.697del p.E233Kfs*11 | Frame Shift Del (DEL) | VAF 10/112 reads (9%) | called by mutect2, varscan2
- CCDC141 | c.3608G>T p.G1203V | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.183); called by muse, mutect2
- CCDC168 | c.13155G>T p.E4385D | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD163 | c.959A>T p.N320I | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP97 | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CHD8 | c.6269G>T p.S2090I (on ENST00000646647 / NM_001170629.2; = p.S1811I on NM_020920.4) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); called by muse, mutect2
- CIT | c.3152G>A p.G1051D | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN6 | c.2138+1G>C p.X713_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2
- COBL | c.3575G>T p.S1192I | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- COL4A6 | c.2582G>T p.G861V | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPB1 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPNE1 | c.889G>T p.G297* (on ENST00000352393; = p.G302* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- CSF2RB | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 172/539 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CSMD3 | c.6283G>C p.G2095R (on ENST00000297405 / NM_001363185.1; = p.G1991R on NM_052900.3) | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CTPS2 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 67/249 reads (27%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CYP2U1 | c.118T>A p.C40S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- DAPK2 | c.905A>T p.N302I | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- DENND2A | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.174); called by muse, varscan2
- DLGAP1 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- DNAH5 | c.11670G>T p.E3890D | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.11669A>G p.E3890G | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DPYSL4 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DST | c.4465T>G p.S1489A (on ENST00000361203 / NM_001374722.1; = p.S1163A on NM_015548.5) | Missense Mutation (SNP) | VAF 45/503 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.553); called by muse, mutect2
- DYNC1H1 | c.3805G>A p.G1269S | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYRK4 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 54/366 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EFHC1 | c.1872T>A p.H624Q | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EIF4B | c.20del p.K7Rfs*11 | Frame Shift Del (DEL) | VAF 29/265 reads (11%) | called by mutect2, pindel, varscan2
- EMSY | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- EN1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); called by muse, mutect2
- EP300 | c.3636_3671+5del p.X1212_splice | Splice Site (DEL) | VAF 60/740 reads (8%) | called by mutect2, pindel
- ERVV-1 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EXOC3 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 51/484 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FCRL4 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L5 | c.1283G>T p.G428V (on ENST00000623019; = p.G433V on NM_001293083.2) | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FGD5 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FLNB | c.2213A>T p.Q738L | Missense Mutation (SNP) | VAF 96/578 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- G3BP1 | c.949A>T p.R317* | Nonsense Mutation (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- GPR12 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GPR84 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.343); called by muse, mutect2
- GRAMD1A | c.1321G>C p.V441L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- H2BC6 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 97/614 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- HELZ | c.5369A>T p.H1790L | Missense Mutation (SNP) | VAF 122/746 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HEPHL1 | c.3378_3380del p.L1127del | In Frame Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- HJURP | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- HMCN2 | c.12196G>C p.D4066H | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.493); called by muse, mutect2
- HMX1 | c.419C>A p.T140K | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- HOOK3 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICAM4 | c.527A>C p.Y176S | Missense Mutation (SNP) | VAF 63/389 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- IGFN1 | c.2807T>A p.L936* (on ENST00000295591 / NM_001367841.1; = p.L3393* on NM_001164586.2) | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- IGHA2 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGSF3 | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ITIH6 | c.3445A>G p.T1149A | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.4371G>C p.M1457I | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- KCNH1 | c.1334G>A p.S445N (on ENST00000271751 / NM_172362.3; = p.S418N on NM_002238.4) | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2
- KCNH1 | c.769G>C p.V257L | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- KIR2DL4 | c.1043C>A p.T348K (on ENST00000396284; = p.T274K on NM_001080770.2) | Missense Mutation (SNP) | VAF 152/788 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHDC10 | c.1080G>T p.M360I | Missense Mutation (SNP) | VAF 65/487 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- KRT1 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LAD1 | c.668A>T p.K223I | Missense Mutation (SNP) | VAF 48/533 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- LARP4B | c.915+1G>T p.X305_splice | Splice Site (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- LHX2 | c.812C>G p.T271R | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LILRA4 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- LRAT | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRP12 | c.2218G>T p.V740L | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MDN1 | c.3466G>T p.A1156S | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEMO1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MICAL3 | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MTMR4 | c.1917G>T p.E639D | Missense Mutation (SNP) | VAF 27/284 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.05); called by muse, mutect2
- MTRES1 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2
- MUC12 | c.15847T>A p.Y5283N (on ENST00000379442; = p.Y5140N on NM_001164462.1) | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC19 | c.1050+1G>T p.X350_splice | Splice Site (SNP) | VAF 30/276 reads (11%) | called by muse, mutect2
- MYCBP2 | c.10516T>A p.L3506I (on ENST00000357337; = p.L3544I on NM_015057.5) | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MYH2 | c.2800G>T p.D934Y | Missense Mutation (SNP) | VAF 86/735 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- MYH4 | c.1426C>A p.L476M | Missense Mutation (SNP) | VAF 86/625 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MYO10 | c.2054G>T p.R685M | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO6 | c.3605G>T p.W1202L (on ENST00000369981; = p.W1192L on NM_004999.4) | Missense Mutation (SNP) | VAF 70/974 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.633); called by muse, mutect2
- NALCN | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCOA6 | c.5063G>A p.G1688D | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- NDST4 | c.1322G>C p.W441S | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NECAB1 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- NKX2-3 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NNT | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- NOTCH3 | c.6491A>T p.N2164I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- NRBP2 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- NRCAM | c.1247C>A p.T416N (on ENST00000379028 / NM_001371124.1; = p.T410N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- NSMAF | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 28/208 reads (13%) | called by muse, mutect2, varscan2
- OPN5 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.175); called by muse, mutect2
- OPN5 | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.215); called by muse, mutect2
- OR11H7 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR2T35 | c.379T>A p.C127S | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR6C68 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- OR8B8 | c.252C>G p.S84R | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); called by muse, mutect2
- OR8I2 | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 32/486 reads (7%) | called by muse, mutect2
- OR8I2 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 32/485 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2
- PAPPA2 | c.5321A>G p.D1774G | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2
- PARD3B | c.2617G>T p.G873C (on ENST00000406610 / NM_001302769.2; = p.G804C on NM_057177.7) | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- PCDHGA2 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PDC | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDC | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- PHF21A | c.1477G>T p.V493F (on ENST00000418153 / NM_001101802.3; = p.V447F on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- POLE | c.1021-6G>C | Splice Region (SNP) | VAF 37/155 reads (24%) | called by muse, mutect2, varscan2
- PRDM1 | c.2336A>T p.N779I | Missense Mutation (SNP) | VAF 40/534 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- PRG2 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.337); called by muse, mutect2
- PRG4 | c.2704A>T p.K902* | Nonsense Mutation (SNP) | VAF 83/805 reads (10%) | called by muse, mutect2
- PTPRH | c.3130G>T p.G1044C | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAPGEF6 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); called by mutect2, varscan2
- RAVER2 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); called by muse, mutect2
- RAVER2 | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- RFC2 | c.584A>T p.D195V (on ENST00000055077 / NM_181471.3; = p.D161V on NM_002914.4) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- RGSL1 | c.1112A>G p.H371R | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.915); called by muse, mutect2
- ROBO3 | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 52/669 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.456); called by muse, mutect2
- ROCK1 | c.605A>T p.D202V | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEZ6L2 | c.2232G>C p.M744I (on ENST00000308713 / NM_001114099.3; = p.M674I on NM_012410.4) | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGK3 | c.52A>T p.I18F | Missense Mutation (SNP) | VAF 43/412 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- SIX2 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- SLC27A3 | c.1328G>A p.C443Y (on ENST00000271857; = p.C315Y on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC45A4 | c.1885A>G p.M629V (on ENST00000517878 / NM_001286646.2; = p.M578V on NM_001080431.2) | Missense Mutation (SNP) | VAF 55/471 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SLC9A2 | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC9A9 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 92/769 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SND1 | c.424A>G p.N142D | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SNX14 | c.1535G>C p.G512A (on ENST00000314673 / NM_001350535.1; = p.G459A on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- SORBS2 | c.1351A>T p.K451* | Nonsense Mutation (SNP) | VAF 61/277 reads (22%) | called by muse, mutect2, varscan2
- SP1 | c.1391G>T p.W464L (on ENST00000327443 / NM_138473.3; = p.W457L on NM_003109.1) | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ST3GAL4 | c.265G>T p.G89W (on ENST00000392669 / NM_001254758.1; = p.G85W on NM_006278.3) | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAB2 | c.4699A>T p.S1567C | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYT7 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- TACR3 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 63/398 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TATDN2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 94/544 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TAX1BP1 | c.1778G>C p.S593T | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D1 | c.911G>T p.S304I | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX35 | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TGFB2 | c.974A>T p.D325V | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLX3 | c.554T>C p.F185S | Missense Mutation (SNP) | VAF 53/375 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMC2 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TNFAIP8L2 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TNPO3 | c.2344G>C p.A782P | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TOGARAM2 | c.1579G>T p.G527W | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TOR4A | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV19 | c.79del p.A27Rfs*13 | Frame Shift Del (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel
- TTK | c.809del p.P270Hfs*10 | Frame Shift Del (DEL) | VAF 21/171 reads (12%) | called by mutect2, pindel, varscan2
- TTN | c.99307G>A p.A33103T (on ENST00000591111; = p.A25679T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/174 reads (16%) | PolyPhen benign (0.109); called by muse, mutect2, varscan2
- UBAP1L | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- UBASH3A | c.339_340del p.C114* | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- UGP2 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2
- UPB1 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VAX2 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNT11 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- XXYLT1 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ZC3H7B | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2
- ZCCHC4 | c.1184A>T p.E395V | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMAT4 | c.452C>G p.A151G | Missense Mutation (SNP) | VAF 84/551 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF106 | c.2876A>G p.E959G | Missense Mutation (SNP) | VAF 88/979 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- ZNF202 | c.1939A>G p.T647A | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2
- ZNF208 | c.1823C>A p.P608H | Missense Mutation (SNP) | VAF 60/457 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ZNF8 | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABRA | c.294C>G p.A98= | Silent (SNP) | VAF 105/682 reads (15%) | catalogued as COSV100357454; called by muse, mutect2, varscan2
- ACKR1 | c.192C>T p.F64= | Silent (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- ANK2 | c.7116C>G p.S2372= | Silent (SNP) | VAF 30/279 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.873T>C p.S291= | Silent (SNP) | VAF 32/278 reads (12%) | catalogued as rs1377873922; called by muse, mutect2, varscan2
- ATP6V0D2 | c.600T>C p.H200= | Silent (SNP) | VAF 20/322 reads (6%) | called by muse, mutect2
- CASR | c.1368G>A p.E456= | Silent (SNP) | VAF 22/288 reads (8%) | called by muse, mutect2
- CDK5 | c.525G>A p.G175= | Silent (SNP) | VAF 36/226 reads (16%) | called by muse, mutect2, varscan2
- CENPE | c.2946A>T p.T982= | Silent (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- CEP68 | c.1782A>T p.P594= | Silent (SNP) | VAF 32/456 reads (7%) | called by muse, mutect2
- CFAP298 | c.732G>T p.L244= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as rs758517253; called by muse, mutect2
- CFTR | c.2262G>T p.V754= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV50077944; called by muse, mutect2
- CHRM4 | c.723G>T p.T241= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs375252473; called by muse, mutect2, varscan2
- CIB3 | c.105G>A p.Q35= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- CLEC4C | c.432G>C p.L144= | Silent (SNP) | VAF 37/278 reads (13%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1368T>C p.C456= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- DACH2 | c.1375T>C p.L459= | Silent (SNP) | VAF 36/149 reads (24%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.453G>T p.A151= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV70548732; called by muse, mutect2, varscan2
- DEFA3 | c.204C>T p.C68= | Silent (SNP) | VAF 70/605 reads (12%) | called by muse, mutect2, varscan2
- DEFB124 | c.99C>T p.A33= | Silent (SNP) | VAF 51/242 reads (21%) | called by muse, mutect2, varscan2
- DHTKD1 | c.2499C>A p.I833= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- ELAPOR2 | c.810G>T p.A270= (on ENST00000450689 / NM_001142749.3; = p.A103= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/252 reads (9%) | catalogued as COSV51889209; called by muse, mutect2
- FAM122B | c.420C>A p.P140= | Silent (SNP) | VAF 65/253 reads (26%) | called by muse, mutect2, varscan2
- GPR12 | c.615C>A p.S205= | Silent (SNP) | VAF 39/371 reads (11%) | called by muse, mutect2, varscan2
- H1-0 | c.204C>T p.I68= | Silent (SNP) | VAF 89/230 reads (39%) | catalogued as rs1053293380; called by muse, mutect2, varscan2
- HCK | c.786C>G p.L262= | Silent (SNP) | VAF 31/174 reads (18%) | catalogued as COSV99394773; called by muse, mutect2, varscan2
- HEATR1 | c.75A>G p.E25= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- HERC4 | c.1005G>A p.R335= | Silent (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.147C>A p.T49= | Silent (SNP) | VAF 70/1244 reads (6%) | called by muse, mutect2
- IGKV1-8 | c.285C>T p.I95= | Silent (SNP) | VAF 56/805 reads (7%) | called by muse, mutect2
- IL17RE | c.1731G>C p.L577= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.828G>T p.G276= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- ITGAE | c.2454C>G p.P818= | Silent (SNP) | VAF 46/280 reads (16%) | called by muse, mutect2, varscan2
- LCE1E | c.120C>A p.V40= | Silent (SNP) | VAF 50/594 reads (8%) | called by muse, mutect2
- LRAT | c.177C>A p.T59= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- LRRC4B | c.2073C>T p.L691= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- LRRC7 | c.2599A>C p.R867= (on ENST00000651989 / NM_001370785.2; = p.R834= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/316 reads (5%) | called by muse, mutect2
- LRRD1 | c.855C>G p.L285= | Silent (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- MACF1 | c.9765A>G p.L3255= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- MAP11 | c.894G>A p.G298= | Silent (SNP) | VAF 36/273 reads (13%) | catalogued as rs1428467533; called by muse, mutect2, varscan2
- MGAM2 | c.2109G>C p.V703= | Silent (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- MPP4 | c.1512T>C p.Y504= | Silent (SNP) | VAF 36/422 reads (9%) | catalogued as rs866136023; called by muse, mutect2
- MUC16 | c.4446C>T p.P1482= | Silent (SNP) | VAF 42/231 reads (18%) | called by muse, mutect2, varscan2
- MUC4 | c.8625A>T p.T2875= | Silent (SNP) | VAF 92/916 reads (10%) | called by muse, mutect2
- MYH7 | c.4803G>A p.L1601= | Silent (SNP) | VAF 34/552 reads (6%) | catalogued as rs397516228; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- NBN | c.1875A>G p.E625= | Silent (SNP) | VAF 58/482 reads (12%) | called by muse, mutect2, varscan2
- NCKAP5 | c.978C>T p.L326= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- NPR2 | c.9G>A p.L3= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- NRCAM | c.1248C>A p.T416= (on ENST00000379028 / NM_001371124.1; = p.T410= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- OR2A12 | c.861C>A p.L287= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as COSV68822155; called by muse, mutect2, varscan2
- OR2T10 | c.228C>A p.V76= | Silent (SNP) | VAF 57/639 reads (9%) | called by muse, mutect2
- OR2T33 | c.858C>A p.L286= | Silent (SNP) | VAF 48/552 reads (9%) | called by muse, mutect2
- OR2T35 | c.786C>A p.P262= | Silent (SNP) | VAF 45/682 reads (7%) | called by muse, mutect2
- OSBPL5 | c.1053G>A p.L351= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV55144270; called by muse, mutect2
- OTUD6A | c.525C>G p.A175= | Silent (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- PATL1 | c.414A>C p.P138= | Silent (SNP) | VAF 28/303 reads (9%) | called by muse, mutect2
- PAX3 | c.462C>T p.I154= | Silent (SNP) | VAF 25/307 reads (8%) | called by muse, mutect2
- PCDHA3 | c.1719C>A p.I573= | Silent (SNP) | VAF 63/456 reads (14%) | catalogued as COSV63543091, COSV63545984; called by muse, mutect2, varscan2
- PDGFRB | c.994C>A p.R332= | Silent (SNP) | VAF 44/287 reads (15%) | catalogued as COSV55805031; called by muse, mutect2, varscan2
- PLXNA4 | c.5395C>T p.L1799= | Silent (SNP) | VAF 35/325 reads (11%) | called by muse, mutect2, varscan2
- PMP2 | c.111C>A p.A37= | Silent (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- POM121L2 | c.192T>A p.P64= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1340294662; called by muse, mutect2, varscan2
- POTEH | c.1002T>C p.N334= | Silent (SNP) | VAF 56/1078 reads (5%) | called by muse, mutect2
- PRSS41 | c.45G>T p.R15= | Silent (SNP) | VAF 28/189 reads (15%) | catalogued as rs755479662; called by muse, mutect2, varscan2
- PSG3 | c.456C>A p.S152= | Silent (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- REG1A | c.120C>T p.T40= | Silent (SNP) | VAF 42/710 reads (6%) | called by muse, mutect2
- RELN | c.10045C>T p.L3349= | Silent (SNP) | VAF 35/345 reads (10%) | catalogued as COSV59013565; called by muse, mutect2, varscan2
- RYR3 | c.10941G>C p.T3647= (on ENST00000389232; = p.T3648= on NM_001036.6) | Silent (SNP) | VAF 43/492 reads (9%) | called by muse, mutect2
- SCN10A | c.2463C>A p.S821= | Silent (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- SEC24B | c.3744G>T p.R1248= | Silent (SNP) | VAF 67/409 reads (16%) | catalogued as COSV54497796; called by muse, mutect2, varscan2
- SEPTIN2 | c.381G>A p.E127= | Silent (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- SH2D3C | c.2211G>T p.P737= (on ENST00000314830 / NM_170600.3; = p.P580= on NM_005489.4) | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV59122221; called by muse, mutect2
- SLC7A9 | c.1276C>T p.L426= | Silent (SNP) | VAF 26/487 reads (5%) | called by muse, mutect2
- SRSF5 | c.642G>T p.R214= | Silent (SNP) | VAF 111/681 reads (16%) | catalogued as rs1476401203; called by muse, mutect2, varscan2
- ST18 | c.9A>G p.A3= | Silent (SNP) | VAF 50/354 reads (14%) | catalogued as rs1324135187; called by muse, varscan2
- SYNE2 | c.13608A>G p.L4536= | Silent (SNP) | VAF 53/443 reads (12%) | called by muse, mutect2, varscan2
- TBC1D10C | c.951C>A p.A317= | Silent (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2
- THSD7A | c.3018C>T p.Y1006= | Silent (SNP) | VAF 52/355 reads (15%) | catalogued as rs1361446475, COSV70260187; called by muse, mutect2, varscan2
- TRDN | c.561G>A p.K187= | Silent (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2
- TRPM5 | c.1284C>G p.L428= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as rs373936003; called by muse, mutect2
- TRRAP | c.6714G>A p.E2238= (on ENST00000359863 / NM_001244580.1; = p.E2220= on NM_003496.3) | Silent (SNP) | VAF 37/318 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.29047C>T p.L9683= (on ENST00000591111; = p.L8756= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- USH1C | c.1254G>T p.L418= | Silent (SNP) | VAF 54/544 reads (10%) | called by muse, mutect2, varscan2
- USPL1 | c.2949A>G p.T983= | Silent (SNP) | VAF 48/324 reads (15%) | called by muse, mutect2, varscan2
- UXS1 | c.963C>T p.V321= | Silent (SNP) | VAF 41/289 reads (14%) | catalogued as rs1558673979; called by muse, mutect2, varscan2
- VN1R5 | c.468C>G p.L156= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs1022638553; called by muse, mutect2
- ZNF846 | c.24G>T p.V8= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- AAK1 | c.*9998C>T | 3'UTR (SNP) | VAF 10/233 reads (4%) | catalogued as rs938288632, COSV100181971; called by muse, mutect2
- AC092656.1 | n.227C>T | RNA (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- AC114741.1 | n.169C>G | RNA (SNP) | VAF 46/414 reads (11%) | called by muse, mutect2, varscan2
- ACTR3BP2 | n.720T>A | RNA (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- AL353804.7 | chrX:73850272 T>A | 5'Flank (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
- APTX | c.-111+80C>G | Intron (SNP) | VAF 91/596 reads (15%) | catalogued as rs539718096; called by muse, mutect2, varscan2
- ASTN1 | c.2482+28C>T | Intron (SNP) | VAF 33/554 reads (6%) | catalogued as rs1406839947; called by muse, mutect2
- C6orf99 | n.1002C>A | RNA (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- CAND1 | c.367+13A>G | Intron (SNP) | VAF 42/372 reads (11%) | catalogued as rs1307362652; called by muse, mutect2, varscan2
- CLVS1 | c.-174C>A | 5'UTR (SNP) | VAF 46/396 reads (12%) | called by muse, mutect2, varscan2
- COG6 | c.541-29G>T | Intron (SNP) | VAF 55/342 reads (16%) | called by muse, mutect2, varscan2
- CYLD | c.1949+22_1949+23del | Intron (DEL) | VAF 21/220 reads (10%) | called by mutect2, pindel, varscan2
- DCHS2 | n.6199G>A | RNA (SNP) | VAF 30/193 reads (16%) | catalogued as COSV61768821; called by muse, mutect2, varscan2
- EPB41L2 | c.2608-61C>T | Intron (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2
- FBLN1 | c.1698-11270T>C | Intron (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- KDM6A | c.3144+30A>T | Intron (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- KIF13A | c.1786+3953C>A | Intron (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2, varscan2
- KIF14 | chr1:200624940 C>T | 5'Flank (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- KLHL7 | c.121-5875T>C | Intron (SNP) | VAF 54/414 reads (13%) | catalogued as rs558888234; called by muse, mutect2, varscan2
- LINC01205 | n.159G>C | RNA (SNP) | VAF 19/263 reads (7%) | called by muse, mutect2
- LINC01555 | n.313A>T | RNA (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- NFATC1 | c.127+4125C>A | Intron (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- NT5C1B | c.1071+146T>C | Intron (SNP) | VAF 40/357 reads (11%) | called by muse, mutect2, varscan2
- OR2A13P | n.668C>A | RNA (SNP) | VAF 31/352 reads (9%) | called by muse, mutect2
- OR2A13P | n.669C>A | RNA (SNP) | VAF 29/351 reads (8%) | called by muse, mutect2
- OR2W5 | n.751G>A | RNA (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- PAPSS2 | c.-14C>A | 5'UTR (SNP) | VAF 60/439 reads (14%) | called by muse, varscan2
- PLCB1 | c.594+2004G>T | Intron (SNP) | VAF 32/344 reads (9%) | called by muse, mutect2
- PPIP5K1 | c.3500-742del | Intron (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel
- RDX | c.1091-71A>C | Intron (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- RPS3 | chr11:75399535 G>T | 5'Flank (SNP) | VAF 33/304 reads (11%) | catalogued as rs1315659461; called by muse, mutect2, varscan2
- SCGB1A1 | c.*19C>G | 3'UTR (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- SDHAP1 | n.1506T>A | RNA (SNP) | VAF 48/786 reads (6%) | called by muse, mutect2
- SNUPN | c.-6+944G>C | Intron (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- SP110 | c.1816-35G>A | Intron (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- SPPL2A | c.1146+204A>T | Intron (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- TCF3 | c.298+79C>T | Intron (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- TMCO1 | c.*1694G>T | 3'UTR (SNP) | VAF 49/378 reads (13%) | called by muse, mutect2, varscan2
- TREML2 | c.-24G>C | 5'UTR (SNP) | VAF 14/134 reads (10%) | called by muse, varscan2
- TRPM3 | c.184-256713G>T | Intron (SNP) | VAF 32/245 reads (13%) | called by muse, mutect2, varscan2
- TSPAN12 | c.-4C>A | 5'UTR (SNP) | VAF 85/681 reads (12%) | called by muse, mutect2, varscan2
- TTC13 | c.901-2309G>T | Intron (SNP) | VAF 25/237 reads (11%) | catalogued as rs763382347; called by muse, mutect2, varscan2
- TTC39C | c.985-933A>G | Intron (SNP) | VAF 39/357 reads (11%) | catalogued as rs1300421080; called by muse, mutect2, varscan2
- UMOD | c.-6G>A | 5'UTR (SNP) | VAF 56/366 reads (15%) | catalogued as COSV100208202, COSV56775936; called by muse, mutect2, varscan2
- UQCRB | c.*4052T>C | 3'UTR (SNP) | VAF 46/487 reads (9%) | called by muse, mutect2
- WNK4 | c.792-106T>C | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- XIRP2 | c.*759C>T | 3'UTR (SNP) | VAF 36/362 reads (10%) | called by muse, mutect2
- XIRP2 | c.*760T>C | 3'UTR (SNP) | VAF 36/362 reads (10%) | called by muse, mutect2
